Somatic mutation profile of tumor specimen TARGET-10-PAPLDL-03A (aliquot TARGET-10-PAPLDL-03A-01D) from TARGET case TARGET-10-PAPLDL, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.3 years (2,677 days).
Specimen TARGET-10-PAPLDL-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 57097816-4c41-4bef-9050-9ea0c552663e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPLDL-10A (Blood Derived Normal), aliquot TARGET-10-PAPLDL-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/336858dc-f650-4d0e-8384-785ecacbccf6

The open-access MAF lists 50 somatic variants for this specimen: 25 protein-altering or splice-affecting, 23 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 23, Frame Shift Ins 1, 3'Flank 1, Nonsense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANO4 | c.1993G>A p.E665K (on ENST00000392977 / NM_001286615.2; = p.E630K on NM_178826.4) | Missense Mutation (SNP) | VAF 113/245 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV54596535; called by muse, mutect2, varscan2
- CACNA1E | c.2770C>T p.R924C | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs757890592, COSV62383300; called by muse, mutect2, varscan2
- CEP112 | c.2414A>T p.Q805L (on ENST00000392769 / NM_001353127.1; = p.Q61L on NM_001037325.3) | Missense Mutation (SNP) | VAF 312/804 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.354); catalogued as COSV58064304; called by muse, mutect2, varscan2
- DNAH11 | c.9236C>T p.S3079L | Missense Mutation (SNP) | VAF 56/345 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.26); catalogued as COSV60951630, COSV60956979; called by muse, mutect2, varscan2
- HMCN1 | c.3022C>T p.P1008S | Missense Mutation (SNP) | VAF 50/212 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54875318; called by muse, mutect2, varscan2
- KRT37 | c.773G>A p.R258Q | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs755993723, COSV56658233; called by muse, mutect2, varscan2
- LRRC42 | c.715G>A p.D239N | Missense Mutation (SNP) | VAF 51/249 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV59960901; called by muse, mutect2, varscan2
- MAP3K15 | c.3035G>A p.R1012H | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs1367846847, COSV58830520; called by muse, mutect2, varscan2
- OR10Q1 | c.935G>A p.R312H | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs1464228910, COSV57469614; called by muse, mutect2, varscan2
- OR4K13 | c.758C>T p.P253L | Missense Mutation (SNP) | VAF 17/172 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs150686832, COSV100237803, COSV59859719; called by muse, mutect2, varscan2
- PAPPA2 | c.3556G>A p.G1186R | Missense Mutation (SNP) | VAF 61/169 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62791427; called by muse, mutect2, varscan2
- PAX5 | c.328T>A p.F110I | Missense Mutation (SNP) | VAF 71/103 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV63907655, COSV63908714; called by muse, mutect2, varscan2
- PLPPR1 | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 44/149 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.104); catalogued as rs1465004638, COSV66453472; called by muse, mutect2, varscan2
- SHROOM3 | c.4583C>T p.P1528L | Missense Mutation (SNP) | VAF 3/66 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as COSV99934960; called by muse, mutect2
- SLFN5 | c.2345G>A p.R782Q | Missense Mutation (SNP) | VAF 96/394 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1234377088, COSV55481324; called by muse, mutect2, varscan2
- SPAG8 | c.122G>A p.R41K | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV52414232; called by muse, mutect2, varscan2
- SPANXN2 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 327/674 reads (49%) | SIFT tolerated (0.4); PolyPhen benign (0.426); catalogued as rs782731457, COSV65128497; called by muse, mutect2, varscan2
- TAFA4 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV55138173; called by muse, mutect2, varscan2
- TOR1AIP2 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.257); catalogued as COSV62625737; called by muse, mutect2
- TRPM1 | c.3820C>T p.R1274* | Nonsense Mutation (SNP) | VAF 47/127 reads (37%) | catalogued as rs761825403, COSV56633639; called by muse, mutect2, varscan2
- ZC3H4 | c.2209C>T p.P737S | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.36); PolyPhen benign (0.32); catalogued as rs1381507058, COSV53413131; called by muse, mutect2, varscan2
- ZNF334 | c.1885G>A p.E629K | Missense Mutation (SNP) | VAF 164/374 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV61618783; called by muse, mutect2, varscan2
- ZNF670 | c.829G>A p.G277R | Missense Mutation (SNP) | VAF 62/393 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV63608153, COSV63608275; called by muse, mutect2, varscan2
- CEP112 | c.2413C>A p.Q805K (on ENST00000392769 / NM_001353127.1; = p.Q61K on NM_001037325.3) | Missense Mutation (SNP) | VAF 307/799 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- MME | c.354_355insGG p.K119Gfs*13 | Frame Shift Ins (INS) | VAF 77/225 reads (34%) | called by mutect2, pindel, varscan2
- AKAP13 | c.6939C>T p.V2313= (on ENST00000394518 / NM_007200.5; = p.V2317= on NM_006738.6) | Silent (SNP) | VAF 25/151 reads (17%) | catalogued as COSV63457951; called by muse, mutect2, varscan2
- ANXA5 | c.132C>T p.S44= | Silent (SNP) | VAF 109/254 reads (43%) | catalogued as rs1319728826, COSV56639027; called by muse, mutect2, varscan2
- CEP152 | c.2556C>T p.T852= | Silent (SNP) | VAF 198/480 reads (41%) | catalogued as COSV57859669; called by muse, mutect2, varscan2
- CLEC1B | c.217C>T p.L73= | Silent (SNP) | VAF 202/502 reads (40%) | catalogued as COSV53725553, COSV53726536; called by muse, mutect2, varscan2
- COL6A3 | c.1080C>T p.D360= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as rs762463347, COSV55081870; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH5 | c.7893G>A p.T2631= | Silent (SNP) | VAF 186/417 reads (45%) | catalogued as rs371810104; called by muse, mutect2, varscan2
- DNAH5 | c.7131C>T p.F2377= | Silent (SNP) | VAF 27/141 reads (19%) | catalogued as rs562255121, COSV54226986; called by muse, mutect2, varscan2
- DSG2 | c.2997G>A p.S999= | Silent (SNP) | VAF 57/128 reads (45%) | catalogued as rs763888499, COSV55199347; ClinVar: likely benign; called by muse, mutect2, varscan2
- FAM47C | c.1248G>A p.S416= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as rs782664966, COSV100792852; called by muse, mutect2, varscan2
- FAT3 | c.10044G>A p.A3348= | Silent (SNP) | VAF 25/64 reads (39%) | catalogued as rs370318087; called by muse, mutect2, varscan2
- FSHR | c.1770C>T p.F590= | Silent (SNP) | VAF 35/93 reads (38%) | catalogued as COSV58623618, COSV58624141; called by muse, mutect2, varscan2
- IL4R | c.1881G>A p.G627= | Silent (SNP) | VAF 3/32 reads (9%) | catalogued as rs1257803582; called by muse, mutect2
- L1CAM | c.3282G>A p.R1094= | Silent (SNP) | VAF 36/73 reads (49%) | catalogued as COSV62828180; called by muse, mutect2, varscan2
- MYH1 | c.1914G>A p.K638= | Silent (SNP) | VAF 40/107 reads (37%) | catalogued as COSV56849001, COSV56849120, COSV99875166; called by muse, mutect2, varscan2
- NLRP5 | c.1626G>A p.R542= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as COSV66764567; called by muse, mutect2
- PTPN3 | c.954G>A p.K318= | Silent (SNP) | VAF 103/256 reads (40%) | catalogued as COSV52706162, COSV99355709; called by muse, mutect2, varscan2
- SGTB | c.744C>T p.A248= | Silent (SNP) | VAF 52/140 reads (37%) | catalogued as rs1281689399, COSV66817852; called by muse, mutect2, varscan2
- TMEM132D | c.1149C>T p.I383= | Silent (SNP) | VAF 18/20 reads (90%) | catalogued as COSV70600994; called by muse, mutect2, varscan2
- TMEM215 | c.231C>T p.V77= | Silent (SNP) | VAF 22/36 reads (61%) | catalogued as COSV61363479; called by muse, mutect2, varscan2
- TRIM66 | c.1575C>T p.L525= | Silent (SNP) | VAF 16/101 reads (16%) | catalogued as COSV55126221; called by muse, mutect2, varscan2
- TUBB2B | c.216G>A p.T72= | Silent (SNP) | VAF 30/64 reads (47%) | catalogued as rs752292801, COSV52533729; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZC3H12C | c.2178C>T p.P726= | Silent (SNP) | VAF 16/95 reads (17%) | catalogued as COSV53709044; called by muse, mutect2, varscan2
- ZNF735 | c.1134G>A p.E378= | Silent (SNP) | VAF 66/155 reads (43%) | catalogued as COSV70034934; called by muse, mutect2, varscan2
- APOBEC3B | c.-26G>A | 5'UTR (SNP) | VAF 45/53 reads (85%) | catalogued as rs369907102, COSV100213709; called by muse, mutect2, varscan2
- TRAJ52 | chr14:22490490 ins GGT | 3'Flank (INS) | VAF 32/246 reads (13%) | called by mutect2, pindel, varscan2
